Gene-level copy-number profile of tumor specimen TCGA-06-0648-01A from TCGA case TCGA-06-0648, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.0 years (28,477 days).
Specimen TCGA-06-0648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.118d5604-532e-462c-a5a2-73f09b60a8d3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0648-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/de835eab-92ca-47d6-873a-0ba1ebaa2cfd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 20; copy number 2: 5,572; copy number 3: 3,865; copy number 4: 45,399; copy number 5: 75; copy number 6: 4,814; copy number 8: 7; copy number 21: 18; copy number 22: 11; copy number 64: 4; copy number 77: 8; copy number 79: 2; copy number 85: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0648-01A-01D-0310-01): tumor purity 0.91, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,029,594, 10 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr10:87,817,928–87,863,533, 3 genes (within-gene range 0–2): CFL1P1, RN7SL78P, KLLN.
- chr10:88,259,129–88,584,530, 2 genes (within-gene range 0–2): AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 46 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:67,265,842–67,352,039, 4 genes, copy number 79–85: GGTA2P, CAND1, AC078983.1, MRPL40P1.
- chr12:67,658,991–67,753,817, 3 genes, copy number 64 (within-gene range 2–64): AC078777.1, LINC02421, AC022513.1.
- chr12:68,035,767–68,036,853, 1 gene, copy number 79: HNRNPA1P70.
- chr12:68,805,011–68,971,570, 8 genes, copy number 77 (within-gene range 2–77): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.
- chr12:69,326,574–69,331,882, 1 gene, copy number 64: AC020656.2.
- chr22:49,773,283–50,261,716, 29 genes, copy number 21–22 (within-gene range 4–22): BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12.

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
